Gene-level copy-number profile of tumor specimen TCGA-DA-A95V-06A from TCGA case TCGA-DA-A95V, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 86.7 years (31,677 days).
Specimen TCGA-DA-A95V-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.d2860b5f-49ac-4a81-a0da-0988f9e64261.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DA-A95V-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/69a7fd16-36e0-4004-9ff3-878683ee02ca

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,131; copy number 2: 6,229; copy number 3: 12,100; copy number 4: 9,443; copy number 5: 8,943; copy number 6: 9,451; copy number 7: 5,961; copy number 8: 2,156; copy number 9: 1,690; copy number 10: 477; copy number 11: 596; copy number 12: 388; copy number 13: 702; copy number 14: 305; copy number 15: 38; copy number 18: 43; copy number 20: 92; copy number 32: 18; copy number 34: 46.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DA-A95V-06A-11D-A371-01): tumor purity 0.55, ploidy 4.2, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 12,409 genes in 48 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–19,075,511, 621 genes, copy number 7–8 (broad region; genes not listed).
- chr1:119,126,539–121,580,524, 72 genes, copy number 14 (broad region; genes not listed).
- chr2:46,166,789–95,197,357, 911 genes, copy number 7–8 (broad region; genes not listed).
- chr3:33,277,025–33,869,707, 10 genes, copy number 12: FBXL2, UBP1, RNU7-110P, RNA5SP128, CLASP2, COX6CP10, AC112220.1, SDAD1P3, AC112220.2, PDCD6IP.
- chr3:54,626,215–90,261,708, 361 genes, copy number 7–8 (within-gene range 5–8) (broad region; genes not listed).
- chr4:19,098,199–24,671,568, 40 genes, copy number 8: AC006840.1, LINC02438, RNA5SP157, AC024595.1, AC024230.1, AC110767.1, AC114728.1, AC098862.1, SLIT2, SLIT2-IT1, MIR218-1, PACRGL, KCNIP4, AC097505.1, AC110296.1, MIR7978, AC096576.7, AC096576.3, AC096576.1, AC096576.2, KCNIP4-IT1, AC096719.1, RNU6-420P, ADGRA3, AC098583.1, AC098583.2, GBA3, CDC42P6, AC097512.1, AC092440.1, RFPL4AP3, AC093607.1, ERVH-1, PPARGC1A, AC092834.1, DHX15, MIR573, RN7SL16P, ATP5MGP3, LINC02473.
- chr4:43,340,875–59,533,898, 222 genes, copy number 8–34 (broad region; genes not listed).
- chr5:58,198–45,228,428, 706 genes, copy number 7–13 (broad region; genes not listed).
- chr5:98,768,650–111,494,886, 124 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr5:148,451,032–155,398,353, 139 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr6:42,564,029–48,952,781, 142 genes, copy number 7–10 (broad region; genes not listed).
- chr6:55,434,373–77,343,654, 216 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr7:70,972–27,844,564, 488 genes, copy number 7–9 (broad region; genes not listed).
- chr7:40,538,127–64,037,958, 415 genes, copy number 7–11 (broad region; genes not listed).
- chr8:41,261,962–145,066,685, 1,614 genes, copy number 7–10 (within-gene range 5–10) (broad region; genes not listed).
- chr9:1,977,784–7,961,224, 108 genes, copy number 7–9 (broad region; genes not listed).
- chr9:13,386,130–18,910,950, 59 genes, copy number 7–10 (within-gene range 1–10): AL583785.1, LINC01235, AL158157.1, LINC00583, PES1P2, AL360089.1, RPL3P11, ATP5PDP3, NFIB, AL441963.1, AL136366.1, AL137017.1, AL159169.1, AL159169.3, AL159169.2, CDCA4P1, ZDHHC21, CER1, FREM1, AL512643.2, AL512643.1, RNU6-1260P, CLCN3P1, LDHAP4, AL592293.1, PSIP1P1, RNU6-559P, TTC39B, RPL7P33, SNAPC3, RNU6-319P, PSIP1, AL513423.1, RN7SL98P, FTH1P12, RNU6-246P, CCDC171, HMGN2P16, RNU6-14P, C9orf92, BNC2, AL449983.1, AL450003.1, BNC2-AS1, LSM1P1, AL162725.2, AL358117.1, RN7SL720P, RPS29P33, AL162725.1, CNTLN, SAMM50P1, SH3GL2, PABPC1P11, ADAMTSL1, AL442638.1, MIR3152, RN7SKP258, RAP1BP1.
- chr9:27,495,857–28,670,286, 11 genes, copy number 7: AL451123.2, IFNK, AL451123.1, C9orf72, CTAGE12P, AL360014.1, AL353746.1, LINGO2, AL451124.1, AL445526.1, KCTD10P1.
- chr9:60,914,407–69,906,227, 197 genes, copy number 7 (broad region; genes not listed).
- chr9:101,028,727–103,689,577, 31 genes, copy number 7 (within-gene range 5–7): PLPPR1, AL161631.1, AL359893.2, ACNATP, BAAT, TRMT112P4, AL359893.1, FYTTD1P1, MRPL50, ZNF189, ALDOB, AL353621.2, TMEM246-AS1, PGAP4, AL353621.1, RNF20, GRIN3A, PPP3R2, MTND3P4, ARL2BPP7, RNU6-329P, AL442644.2, AL442644.1, LINC00587, ZYG11AP1, AL365396.1, CYLC2, AL589823.1, LINC01492, AL390962.1, RNA5SP291.
- chr11:59,214,406–62,299,075, 137 genes, copy number 10 (broad region; genes not listed).
- chr11:65,695,552–65,921,563, 19 genes, copy number 9: RN7SL309P, KAT5, RNASEH2C, KRT8P26, AP001266.2, AP5B1, OVOL1, OVOL1-AS1, AP001266.1, CFL1, SNX32, MUS81, EFEMP2, CTSW, FIBP, CCDC85B, FOSL1, C11orf68, DRAP1.
- chr11:66,614,964–71,252,577, 160 genes, copy number 7–13 (broad region; genes not listed).
- chr11:72,047,873–72,674,591, 34 genes, copy number 10: RNU6-72P, MIR3165, AP000812.4, LRTOMT, LAMTOR1, AP000812.3, ANAPC15, FOLR3, RPEP6, FOLR1P1, AP000812.1, AP000812.2, FOLR1, FOLR2, INPPL1, PHOX2A, AP000593.2, AP000593.4, AP000593.1, CLPB, AP000593.3, AP002892.2, AP002892.1, AP003785.1, ART2BP, ART2P, AP005019.2, AP005019.1, LINC01537, PDE2A, PDE2A-AS2, MIR139, RNU7-105P, PDE2A-AS1.
- chr11:73,510,658–74,009,085, 20 genes, copy number 10: AP000763.2, HMGN2P38, AP000860.1, PLEKHB1, RAB6A, AP002993.1, AP002770.1, MRPL48, RN7SKP243, CCDC58P5, COA4, PAAF1, ARPC3P4, DNAJB13, AP003717.1, UCP2, AP003717.4, AP003717.2, AP003717.3, UCP3.
- chr11:74,482,250–74,949,200, 17 genes, copy number 9 (within-gene range 5–9): CYCSP27, AP001372.4, LIPT2, AP001372.2, POLD3, RANP3, RN7SKP297, CHRDL2, AP001324.3, MIR4696, AP001324.2, AP001324.1, RNF169, XRRA1, AP000560.1, RN7SL239P, AP001992.1.
- chr11:76,591,023–79,989,630, 68 genes, copy number 8 (broad region; genes not listed).
- chr12:66,767–42,717,120, 921 genes, copy number 7–13 (broad region; genes not listed).
- chr14:18,333,726–30,297,043, 521 genes, copy number 10–20 (within-gene range 4–20) (broad region; genes not listed).
- chr15:19,878,555–23,687,305, 174 genes, copy number 11 (broad region; genes not listed).
- chr15:24,908,932–33,866,121, 296 genes, copy number 11–12 (within-gene range 3–12) (broad region; genes not listed).
- chr15:100,547,765–101,933,350, 54 genes, copy number 8: AC027020.2, RNU6-322P, PRKXP1, AC027020.1, LINS1, RNU6-181P, ASB7, Y_RNA, AC090695.1, AC087762.1, AC087762.2, AC015712.3, AC015712.1, AC015712.6, AC015712.4, AC015712.5, ALDH1A3, AC015712.7, AC015712.2, LRRK1, AC090907.1, AC090907.2, AC090907.3, AC019254.2, AC019254.1, CHSY1, SELENOS, SNRPA1, PCSK6, AC023024.1, AC023024.2, PCSK6-AS1, AC090164.2, AC090164.3, AC090164.4, SNRPCP18, AC090164.1, LINC02348, TM2D3, RNU6-807P, TARS3, AC027559.1, DNM1P47, GOLGA8VP, RN7SL209P, OR4F6, OR4F15, OR4F14P, OR4F13P, OR4F28P, WBP1LP5, AC140725.2, OR4F4, OR4G2P.
- chr17:13,755,574–27,431,623, 429 genes, copy number 7–9 (within-gene range 5–9) (broad region; genes not listed).
- chr17:50,693,198–83,095,122, 949 genes, copy number 7–10 (broad region; genes not listed).
- chr18:47,390–7,135,819, 147 genes, copy number 8–11 (broad region; genes not listed).
- chr19:15,737,985–27,794,005, 435 genes, copy number 7–12 (within-gene range 4–12) (broad region; genes not listed).
- chr19:30,219,666–38,370,943, 301 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr20:87,250–31,390,590, 583 genes, copy number 7 (broad region; genes not listed).
- chr20:40,121,041–60,083,872, 443 genes, copy number 7–8 (broad region; genes not listed).
- chr22:40,673,484–46,679,790, 196 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 797. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
